Somatic mutation profile of tumor specimen TARGET-10-PAPCUI-09A (aliquot TARGET-10-PAPCUI-09A-01D) from TARGET case TARGET-10-PAPCUI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,524 days).
Specimen TARGET-10-PAPCUI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 770a66a4-54b7-463d-9eb3-3f4920a63654.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPCUI-10A (Blood Derived Normal), aliquot TARGET-10-PAPCUI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27b6bb99-5b1d-4c20-8d53-aaba33ddc8b4

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Nonsense Mutation 2, Splice Region 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.16360C>T p.R5454* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs267607239, CM105484, COSV56425484; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 29/100 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERC2 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs1440705306, COSV55612369; called by mutect2, varscan2
- GBF1 | c.2333G>A p.R778Q (on ENST00000369983 / NM_001377137.1; = p.R777Q on NM_004193.3) | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs778886057; called by muse, mutect2, varscan2
- INPP4B | c.969G>T p.G323= | Splice Region (SNP) | VAF 5/79 reads (6%) | catalogued as rs1307165203; called by muse, mutect2
- KCNC1 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as COSV99789096; called by muse, mutect2, varscan2
- TC2N | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.283); catalogued as rs758068918, COSV61746872; called by muse, mutect2, varscan2
- TP63 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs757536818, COSV53205770; called by muse, mutect2, varscan2
- EPC1 | c.1697G>T p.C566F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.395); called by mutect2, varscan2
- KCNJ15 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NEK8 | c.827+8C>A | Splice Region (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- NKAP | c.1001G>C p.R334T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- PROS1 | c.841A>T p.S281C | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- TMEM104 | c.1008C>A p.D336E | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF124 | c.193T>A p.Y65N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ZNF521 | c.2214G>T p.Q738H | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF804B | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDON | c.1198+117C>T | Intron (SNP) | VAF 5/19 reads (26%) | catalogued as rs746208734; called by muse, mutect2, varscan2
- XIAP | c.*6179C>A | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
